Somatic mutation profile of tumor specimen TCGA-B0-4823-01A (aliquot TCGA-B0-4823-01A-02D-1421-08) from TCGA case TCGA-B0-4823, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 88.4 years (32,290 days).
Specimen TCGA-B0-4823-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ac6b6de-a6f5-4485-845a-7df2ff4e565a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-4823-11A (Solid Tissue Normal), aliquot TCGA-B0-4823-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12274fd6-a6a4-4c77-9306-e2560b1c36f4

The open-access MAF lists 123 somatic variants for this specimen: 96 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 26, Frame Shift Del 7, Nonsense Mutation 6, Splice Site 3, In Frame Del 3, Frame Shift Ins 2, Intron 1, In Frame Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.160T>A p.C54S | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV66057538; called by muse, mutect2, varscan2
- ABCC11 | c.697A>T p.R233W | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV62321347; called by muse, mutect2, varscan2
- ACVR1B | c.652T>A p.F218I | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57775003, COSV57778426; called by muse, varscan2
- ANK1 | c.3197T>G p.M1066R | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV55873223; called by muse, mutect2, varscan2
- ASIC3 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52520516; called by muse, mutect2, varscan2
- ASXL3 | c.917C>G p.A306G | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52456541, COSV52457687; called by muse, mutect2, varscan2
- BPTF | c.5506A>T p.K1836* | Nonsense Mutation (SNP) | VAF 78/214 reads (36%) | catalogued as COSV58831595; called by muse, mutect2, varscan2
- C5orf22 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as COSV57597473; called by muse, mutect2
- CCDC88B | c.1933G>T p.G645C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.443); catalogued as COSV57264914; called by muse, mutect2, varscan2
- CD38 | c.317A>G p.Y106C | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56888474; called by muse, mutect2, varscan2
- CDCA2 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 69/228 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as COSV57944381; called by muse, mutect2, varscan2
- CELF4 | c.1441G>C p.D481H | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV58446858; called by muse, mutect2, varscan2
- CHD7 | c.5380C>A p.L1794I | Missense Mutation (SNP) | VAF 61/268 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV71107265; called by muse, mutect2, varscan2
- CHERP | c.1762C>A p.H588N | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV52222388, COSV99550530; called by muse, mutect2, varscan2
- COL6A3 | c.6329G>C p.G2110A | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55079933, COSV55091796; called by muse, mutect2, varscan2
- DNAH7 | c.5270T>A p.L1757* | Nonsense Mutation (SNP) | VAF 20/90 reads (22%) | catalogued as COSV56752239; called by muse, mutect2, varscan2
- DNMT3B | c.1491G>T p.R497= | Splice Region (SNP) | VAF 18/84 reads (21%) | catalogued as COSV52415067; called by muse, mutect2, varscan2
- DOCK7 | c.2480G>A p.R827Q | Missense Mutation (SNP) | VAF 73/288 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs78144896, COSV51996162; called by muse, mutect2, varscan2
- DUS2 | c.1259A>C p.K420T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62707865; called by muse, mutect2, varscan2
- EIF4G1 | c.4241G>C p.G1414A (on ENST00000346169 / NM_198241.3; = p.G1219A on NM_004953.5) | Missense Mutation (SNP) | VAF 124/270 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV59989226; called by muse, mutect2, varscan2
- ELF2 | c.1261A>G p.T421A (on ENST00000379550 / NM_001331036.2; = p.T361A on NM_006874.4) | Missense Mutation (SNP) | VAF 65/221 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV55491662; called by muse, mutect2, varscan2
- FBXO7 | c.356A>C p.Q119P | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV56675988; called by muse, mutect2
- FMNL1 | c.1474C>A p.L492M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.735); catalogued as COSV58955187; called by muse, mutect2, varscan2
- GRTP1 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64901724; called by muse, mutect2, varscan2
- HCK | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1039969128, COSV52940292, COSV52940725; called by muse, mutect2, varscan2
- IDO2 | c.278G>C p.G93A (on ENST00000389060; = p.G106A on NM_194294.2) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.831); catalogued as COSV58423662; called by muse, mutect2, varscan2
- IGKV3-15 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 39/357 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs1240281110; called by muse, mutect2
- INSIG1 | c.753A>G p.I251M | Missense Mutation (SNP) | VAF 86/318 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60919741; called by muse, mutect2, varscan2
- KRT74 | c.167A>T p.N56I | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV59770542; called by muse, mutect2
- KRTAP10-4 | c.27C>G p.S9R | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59952040; called by muse, mutect2, varscan2
- MAP1LC3A | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as rs1308774124, COSV54160480, COSV99465926; called by muse, mutect2, varscan2
- MB21D2 | c.1467A>T p.K489N | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV66661657; called by muse, mutect2, varscan2
- MCCC2 | c.791A>G p.D264G | Missense Mutation (SNP) | VAF 133/321 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV60152855; called by muse, mutect2, varscan2
- MCM2 | c.919C>A p.R307S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV54032088; called by muse, mutect2, varscan2
- MECOM | c.3095G>A p.W1032* (on ENST00000468789 / NM_001105078.4; = p.W1220* on NM_004991.4) | Nonsense Mutation (SNP) | VAF 61/164 reads (37%) | catalogued as COSV52959790; called by muse, mutect2, varscan2
- MMP12 | c.365C>G p.T122R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58259072; called by muse, mutect2, varscan2
- MSN | c.1600G>T p.D534Y | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.678); catalogued as COSV64303234; called by muse, mutect2
- MTCH1 | c.992T>C p.V331A (on ENST00000373627 / NM_001271641.1; = p.V314A on NM_014341.2) | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV65319682; called by muse, mutect2, varscan2
- MYH6 | c.749G>A p.R250K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV62447985; called by muse, mutect2, varscan2
- NLRC5 | c.4622C>G p.A1541G | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.165); catalogued as COSV52649317; called by muse, mutect2, varscan2
- NOD1 | c.2323T>A p.Y775N | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.735); catalogued as COSV56110836; called by muse, mutect2, varscan2
- NUP42 | c.1098T>A p.N366K | Missense Mutation (SNP) | VAF 86/348 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.086); catalogued as COSV51728723; called by muse, mutect2, varscan2
- PIGL | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs762056517, CD152949, COSV51961436; called by muse, mutect2, varscan2
- PLBD1 | c.602A>T p.D201V | Missense Mutation (SNP) | VAF 61/293 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53691843; called by muse, mutect2, varscan2
- PPIL4 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV53566182; called by mutect2, varscan2
- PPRC1 | c.1037T>A p.L346Q | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53383157; called by muse, mutect2, varscan2
- PRC1 | c.1262T>A p.F421Y | Missense Mutation (SNP) | VAF 172/669 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62694163; called by muse, mutect2, varscan2
- PRDX5 | c.469T>G p.F157V | Missense Mutation (SNP) | VAF 92/357 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs372183360, COSV50008526; called by muse, mutect2, varscan2
- PRG4 | c.1046A>G p.E349G | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs758400773, COSV66599492; called by muse, mutect2, varscan2
- PTPRF | c.5212C>G p.L1738V | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63442561; called by muse, mutect2, varscan2
- PXDN | c.3848G>C p.R1283P | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV53227195, COSV53245768; called by muse, varscan2
- PZP | c.2694G>C p.E898D | Missense Mutation (SNP) | VAF 79/211 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.339); catalogued as COSV54354622, COSV54369483; called by muse, mutect2, varscan2
- RCOR2 | c.385A>G p.T129A | Missense Mutation (SNP) | VAF 115/432 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV56849403; called by muse, mutect2, varscan2
- RMI1 | c.167G>T p.W56L | Missense Mutation (SNP) | VAF 63/243 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57935278; called by muse, mutect2
- RMI1 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 63/242 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57935288; called by muse, mutect2
- RRP15 | c.19G>C p.D7H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as rs759297754, COSV65117285; called by muse, varscan2
- SCLT1 | c.1851A>C p.K617N | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55401688; called by muse, mutect2, varscan2
- SDF4 | c.907A>G p.M303V | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs989656770, COSV55417712; called by muse, mutect2, varscan2
- SHROOM3 | c.4963G>A p.V1655I | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV56023416; called by muse, mutect2, varscan2
- SIX6 | c.583C>G p.Q195E | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.065); catalogued as COSV59801570; called by muse, mutect2, varscan2
- SLC22A10 | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60420087; called by muse, mutect2, varscan2
- SLC32A1 | c.1048C>T p.L350F | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.102); catalogued as COSV54145718; called by muse, mutect2, varscan2
- SNED1 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.463); catalogued as rs1164076623, COSV60019307; called by muse, mutect2, varscan2
- SSTR3 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.251); catalogued as rs371258114; called by muse, varscan2
- TFPI | c.528A>C p.E176D | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as COSV51898767; called by muse, mutect2, varscan2
- THRA | c.723+2T>A p.X241_splice | Splice Site (SNP) | VAF 42/151 reads (28%) | catalogued as COSV52840802; called by muse, mutect2, varscan2
- THSD7B | c.2966T>G p.I989S | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV55655497; called by muse, mutect2, varscan2
- TMEM54 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs780609869, COSV61275501; called by muse, mutect2, varscan2
- TNS2 | c.2085G>C p.E695D (on ENST00000314250 / NM_170754.4; = p.E705D on NM_015319.2) | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.482); catalogued as COSV56852364; called by muse, mutect2, varscan2
- TSNARE1 | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV56170912; called by muse, mutect2
- UGT2A1 | c.833T>G p.L278W | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54138206; called by muse, mutect2, varscan2
- USH2A | c.14766G>A p.W4922* | Nonsense Mutation (SNP) | VAF 32/110 reads (29%) | catalogued as CD140459, COSV56329068; called by muse, mutect2, varscan2
- VEGFD | c.15G>T p.W5C | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); catalogued as rs1485258367, COSV52908946; called by muse, mutect2, varscan2
- VPS13D | c.9404T>G p.M3135R | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.139); catalogued as COSV50622109; called by muse, mutect2, varscan2
- ZMYM2 | c.179T>A p.V60D | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.997); catalogued as rs1260408540, COSV67032281; called by muse, mutect2, varscan2
- ZNF77 | c.385C>G p.L129V | Missense Mutation (SNP) | VAF 78/324 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV58821375; called by muse, mutect2, varscan2
- ZW10 | c.2118C>A p.N706K | Missense Mutation (SNP) | VAF 123/511 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs1028217411, COSV52314883; called by muse, mutect2, varscan2
- ANKRD26 | c.4797_4799del p.T1600del | In Frame Del (DEL) | VAF 43/142 reads (30%) | called by pindel, varscan2
- CARD17 | c.24del p.K9Rfs*14 | Frame Shift Del (DEL) | VAF 135/563 reads (24%) | called by mutect2, pindel, varscan2
- CCL4L2 | c.172T>G p.C58G | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- DPY19L1 | c.331-21_331del p.X111_splice | Splice Site (DEL) | VAF 26/125 reads (21%) | called by mutect2, pindel
- ECHDC1 | c.81del p.G28Dfs*16 (on ENST00000531967 / NM_001139510.1; = p.G22Dfs*16 on NM_018479.3) | Frame Shift Del (DEL) | VAF 49/174 reads (28%) | called by mutect2, pindel, varscan2
- KIF13A | c.5093del p.S1698Yfs*5 | Frame Shift Del (DEL) | VAF 27/133 reads (20%) | called by mutect2, pindel, varscan2
- KIR3DL3 | c.279C>A p.Y93* | Nonsense Mutation (SNP) | VAF 93/336 reads (28%) | called by muse, mutect2, varscan2
- MON2 | c.531del p.F177Lfs*15 | Frame Shift Del (DEL) | VAF 99/597 reads (17%) | called by mutect2, pindel, varscan2
- PRAMEF10 | c.1057A>T p.T353S | Missense Mutation (SNP) | VAF 62/460 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, varscan2
- PSMA4 | c.580_581insGCAAA p.I194Sfs*6 | Frame Shift Ins (INS) | VAF 32/190 reads (17%) | called by mutect2, varscan2
- PSMA4 | c.582_586dup p.V196Afs*4 | Frame Shift Ins (INS) | VAF 32/199 reads (16%) | called by mutect2*, pindel, varscan2*
- SCAMP4 | c.289T>G p.F97V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, varscan2
- SEC16A | c.3062_3064del p.Q1021_S1022delinsR | In Frame Del (DEL) | VAF 15/52 reads (29%) | called by mutect2, pindel, varscan2
- SH3GL1 | c.652del p.L218Wfs*118 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- SMARCA4 | c.1156_1158dup p.E386dup | In Frame Ins (INS) | VAF 36/151 reads (24%) | called by mutect2, pindel, varscan2
- SPTAN1 | c.6675-1_6689del p.X2225_splice | Splice Site (DEL) | VAF 144/937 reads (15%) | called by mutect2, pindel, varscan2
- TMEM38A | c.842_859del p.K281_L286del | In Frame Del (DEL) | VAF 17/118 reads (14%) | called by mutect2, pindel
- VHL | c.348_349del p.W117Afs*14 | Frame Shift Del (DEL) | VAF 70/235 reads (30%) | called by mutect2, pindel, varscan2
- ZC3HC1 | c.1113del p.T372Pfs*7 | Frame Shift Del (DEL) | VAF 37/168 reads (22%) | called by mutect2, pindel, varscan2
- A2ML1 | c.1794C>A p.V598= | Silent (SNP) | VAF 107/286 reads (37%) | catalogued as COSV55285853; called by muse, mutect2, varscan2
- ABHD1 | c.24C>G p.P8= | Silent (SNP) | VAF 34/136 reads (25%) | catalogued as COSV53148430; called by muse, mutect2, varscan2
- AFF4 | c.2451G>A p.G817= | Silent (SNP) | VAF 71/327 reads (22%) | catalogued as COSV54791567; called by muse, mutect2, varscan2
- AGO1 | c.1545C>T p.L515= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as COSV64594696; called by muse, mutect2, varscan2
- AHNAK2 | c.5277C>G p.P1759= | Silent (SNP) | VAF 102/186 reads (55%) | catalogued as COSV60908108; called by muse, mutect2, varscan2
- CFAP69 | c.2535C>T p.N845= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs558288448, COSV60184206; called by muse, mutect2, varscan2
- DGAT1 | c.1359C>G p.G453= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV60046933; called by muse, mutect2, varscan2
- ENTPD5 | c.48T>C p.C16= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV58220681; called by muse, mutect2, varscan2
- EPB41L2 | c.2931G>A p.R977= | Silent (SNP) | VAF 83/339 reads (24%) | catalogued as COSV61353200; called by muse, mutect2, varscan2
- FBH1 | c.324T>C p.S108= (on ENST00000362091 / NM_178150.3; = p.S159= on NM_032807.4) | Silent (SNP) | VAF 40/129 reads (31%) | catalogued as rs1161837164, COSV62981611; called by muse, mutect2, varscan2
- GALNT10 | c.627T>G p.L209= | Silent (SNP) | VAF 150/344 reads (44%) | catalogued as COSV51720502; called by muse, mutect2, varscan2
- HDAC6 | c.2562G>A p.K854= | Silent (SNP) | VAF 25/41 reads (61%) | catalogued as COSV61927525; called by muse, mutect2, varscan2
- KRT74 | c.165G>T p.G55= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV59770551; called by muse, mutect2
- LTA4H | c.345T>C p.A115= | Silent (SNP) | VAF 43/210 reads (20%) | catalogued as COSV57381600; called by muse, mutect2, varscan2
- MAGI2 | c.201G>T p.L67= | Silent (SNP) | VAF 39/127 reads (31%) | catalogued as COSV62634806; called by muse, mutect2, varscan2
- MAN1B1 | c.1827C>T p.R609= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as rs201933207, COSV65370939; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRR13 | c.306A>G p.A102= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as COSV65768913; called by muse, mutect2, varscan2
- PSMA2 | c.261G>T p.V87= | Silent (SNP) | VAF 30/155 reads (19%) | catalogued as COSV55030987, COSV55031305; called by muse, mutect2, varscan2
- RABL6 | c.363G>A p.Q121= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV61033277; called by muse, mutect2, varscan2
- RPIA | c.615C>T p.L205= | Silent (SNP) | VAF 39/175 reads (22%) | catalogued as rs1440733627, COSV52168158; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCNN1A | c.717G>A p.Q239= | Silent (SNP) | VAF 10/306 reads (3%) | catalogued as COSV57434080; called by muse, mutect2
- SIGLEC1 | c.2211C>G p.G737= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as COSV52458792; called by muse, mutect2, varscan2
- SLC12A7 | c.2223G>A p.E741= | Silent (SNP) | VAF 92/196 reads (47%) | catalogued as COSV53754630; called by muse, mutect2, varscan2
- TRDN | c.2004G>A p.K668= | Silent (SNP) | VAF 33/137 reads (24%) | catalogued as COSV62113658, COSV62134764; called by muse, mutect2, varscan2
- TSC2 | c.1659C>T p.Y553= | Silent (SNP) | VAF 80/286 reads (28%) | catalogued as rs1358358656, COSV54756269; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.42936C>A p.T14312= (on ENST00000591111; = p.T6888= on NM_003319.4) | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs769989672, COSV59893381; called by muse, mutect2, varscan2
- SAMD14 | c.823-125C>A | Intron (SNP) | VAF 12/41 reads (29%) | catalogued as COSV50303264; called by muse, mutect2, varscan2
